Somatic mutation profile of tumor specimen 0DD53J from CCDI case PBBLPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,123 days).
Specimen 0DD53J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d65a1cb5-edf6-4af2-9e82-ea65dbbb3df7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD53F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a1b9633-78e1-4527-bdfb-61f07e53ab05

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC6 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs755377100; called by muse, mutect2, varscan2
- PLCH2 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1306789279; called by muse, mutect2, varscan2
- TTN | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 63/167 reads (38%) | PolyPhen possibly damaging (0.807); catalogued as rs200848334; called by muse, mutect2, varscan2
- NBR1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- RGS3 | c.3506G>A p.G1169E (on ENST00000350696 / NM_001282923.2; = p.G888E on NM_130795.4) | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX4 | c.5983A>G p.I1995V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.208); called by mutect2, varscan2
- COA4 | c.*53C>G | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- ENOSF1 | c.-3G>T | 5'UTR (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100360835; called by mutect2, varscan2
- MAPKAPK3 | c.-25C>G | 5'UTR (SNP) | VAF 9/114 reads (8%) | catalogued as rs1433985262; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/102 reads (16%) | called by muse, varscan2
